Gene-level copy-number profile of tumor specimen AP-YF3B-S9 from APOLLO case AP-YF3B, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3.
Specimen AP-YF3B-S9: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7d504009-f24c-4192-a88a-297a958506e4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-YF3B-M7 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/03a427ef-9528-4e03-be47-ec237bdd43d3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 8,572; copy number 2: 47,839; copy number 3: 1,638; copy number 4: 185; copy number 5: 125; copy number 6: 14; copy number 7: 4.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:90,261,414–90,261,708, 1 gene: HSPE1P19.
- chr3:196,867,856–196,934,714, 2 genes (within-gene range 0–2): SENP5, AC016949.1.
- chr7:62,275,361–62,275,678, 1 gene: AC128676.1.
- chr7:63,768,257–63,771,047, 1 gene: CICP24.
- chr9:15,588,355–15,588,615, 1 gene (within-gene range 0–1): HMGN2P16.
- chr9:40,767,870–40,883,763, 2 genes (within-gene range 0–1): AL353626.1, AL353626.2.
- chr11:48,880,111–48,902,181, 3 genes: AC027369.6, AC027369.3, AC027369.4.
- chr12:34,149,839–34,166,954, 3 genes: AC140847.1, AC140847.3, TUBB8P4.
- chr13:100,027,769–100,028,174, 1 gene: NDUFA12P1.
- chr13:100,062,296–100,063,601, 1 gene: ASNSP3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 143 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:167,888,414–167,888,715, 1 gene, copy number 6: MEMO1P3.
- chr6:38,675,925–38,703,145, 1 gene, copy number 6: GLO1.
- chr6:39,792,298–42,693,505, 74 genes, copy number 5–6 (broad region; genes not listed).
- chr14:106,865,627–106,879,812, 4 genes, copy number 5: IGHVII-78-1, IGHV3-79, IGHV7-81, IGHVIII-82.
- chr18:21,240,675–23,437,961, 49 genes, copy number 5: AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1.
- chr18:24,426,634–25,056,760, 14 genes, copy number 5–7: IMPACT, Y_RNA, AC007922.2, HRH4, AC007922.1, AC007922.3, EIF4A3P1, LINC01915, RAC1P1, PPIAP57, AC018697.1, LINC01894, WBP2P1, AC104961.1.

Autosomal genes at a single copy (total copy number 1): 7,189. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
